TCGA case TCGA-AA-3713 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/57a2044d-20cc-4d02-b268-ce570a0fabe3

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 68 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 68.2 years (24,927 days); Year of diagnosis: 2005; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R2; Days to last follow up: 579 days (1.6 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 244 days; Days to treatment end: 456 days (1.2 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 275 days; Days to treatment end: 306 days; Treatment dose: 50 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 275 days; Days to treatment end: 306 days; Treatment dose: 50 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Primary Tumor Field.
2. Prior malignancy of the peritoneum (histology not recorded by GDC). AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Prior malignancy of the sigmoid colon (histology not recorded by GDC). AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 30 days; Disease response: With Tumor.
- Days to follow up: 579 days (1.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 83.68 ng/mL.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3713-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-AA-3713-01A-02-BS2: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 73; Percent normal cells: 44; Percent necrosis: 1; Percent lymphocyte infiltration: 1.
  Slide TCGA-AA-3713-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 19; Percent necrosis: 1; Percent lymphocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-AA-3713-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-3713-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 83.68; KRAS gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy histological type: Malignant neoplasm of colon.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -548.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Retroperitoneum and peritoneum; Other malignancy histological type: Secondary malignant neoplasm of respiratory and digestive organs.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy of the retroperitoneum and peritoneum and sigmoid colon. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 579 days; disease-specific survival: no event (censored), 579 days; progression-free interval: no event (censored), 579 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-3713-01A-21D-1717-01): tumor purity 0.56, ploidy 2.05, whole-genome doublings 0.
